CGCI case BLGSP-71-29-00530 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/28e2fe70-f0fb-4fa2-8fe8-c1ce7300c571

Demographics
Sex at birth: male.

Biospecimens (1 sample)
- Sample BLGSP-71-29-00530-50A: Sample type: Cell Lines; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Derived Cell Line; Preservation method: Frozen.
